Somatic mutation profile of tumor specimen 0DKDDI from CCDI case PBBXDF, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.4 years (5,643 days).
Specimen 0DKDDI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afa53f97-257d-43d4-b5c8-f8b900747662.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKDBT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1531a706-c889-432e-a53f-74c5aaf2bac4

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 2, Missense Mutation 2, 3'UTR 1, 5'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PCDH17 | c.122A>G p.D41G | Missense Mutation (SNP) | VAF 33/256 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RALBP1 | c.872G>T p.C291F | Missense Mutation (SNP) | VAF 56/679 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.303); called by muse, mutect2
- HEPH | c.3288G>T p.L1096= (on ENST00000343002; = p.L829= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 105/390 reads (27%) | called by muse, mutect2, varscan2
- INHBC | c.1029C>T p.D343= | Silent (SNP) | VAF 55/456 reads (12%) | called by muse, mutect2, varscan2
- MOB2 | c.-41C>A | 5'UTR (SNP) | VAF 3/13 reads (23%) | called by muse, varscan2
- VSIG1 | c.213+3292G>A | Intron (SNP) | VAF 155/458 reads (34%) | catalogued as rs774749089, COSV99480281; called by muse, mutect2, varscan2
- ZFYVE27 | c.*9G>A | 3'UTR (SNP) | VAF 19/397 reads (5%) | catalogued as COSV100519280, COSV61747348; called by muse, mutect2
